Somatic mutation profile of tumor specimen TCGA-TM-A84Q-01A (aliquot TCGA-TM-A84Q-01A-11D-A36O-08) from TCGA case TCGA-TM-A84Q, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Astrocytoma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.9 years (11,668 days).
Specimen TCGA-TM-A84Q-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c3b5a9ab-10df-4588-b906-e3c7853942ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84Q-10A (Blood Derived Normal), aliquot TCGA-TM-A84Q-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/464f4cfd-1861-4bad-8abe-f55180e84f00

The open-access MAF lists 28 somatic variants for this specimen: 23 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 4, Splice Site 1, In Frame Del 1, Nonsense Mutation 1, 3'UTR 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 36/70 reads (51%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 47/54 reads (87%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs587782082, COSV52662247, COSV52676356, COSV52892337, COSV52908430; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- AMPD1 | c.306A>C p.E102D | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as COSV100815050; called by muse, mutect2
- C4BPA | c.359G>A p.R120H | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs867500835, CM132732, COSV65536149; called by muse, mutect2, varscan2
- DENND5A | c.3570C>G p.N1190K | Missense Mutation (SNP) | VAF 10/85 reads (12%) | SIFT tolerated (0.77); PolyPhen benign (0.079); catalogued as COSV100064745; called by muse, mutect2, varscan2
- DIAPH1 | c.707A>G p.E236G | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.309); catalogued as COSV99526644; called by muse, mutect2, varscan2
- F2RL1 | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 36/423 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1176513304, COSV56995627; called by muse, mutect2
- FMNL3 | c.377G>A p.R126Q | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.661); catalogued as rs1444059344, COSV53301283; called by mutect2, varscan2
- GRM3 | c.492C>G p.F164L | Missense Mutation (SNP) | VAF 45/142 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100862579, COSV64479668; called by muse, mutect2, varscan2
- OR5R1 | c.641T>C p.V214A | Missense Mutation (SNP) | VAF 23/55 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100393456; called by muse, mutect2, varscan2
- PGLYRP4 | c.273C>A p.D91E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs370345526; called by muse, mutect2, varscan2
- PPP1R21 | c.1028C>G p.S343* | Nonsense Mutation (SNP) | VAF 186/328 reads (57%) | catalogued as COSV99682115; called by muse, varscan2
- SPTBN4 | c.810G>C p.E270D | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV100151007; called by muse, mutect2, varscan2
- TDO2 | c.268T>A p.L90M | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.447); catalogued as COSV101539751; called by muse, mutect2, varscan2
- TNNT3 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV53489400; called by muse, mutect2, varscan2
- TTN | c.65308G>A p.G21770S (on ENST00000591111; = p.G14346S on NM_003319.4) | Missense Mutation (SNP) | VAF 55/188 reads (29%) | PolyPhen possibly damaging (0.88); catalogued as rs767075037, COSV100615059; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- WAC | c.1807A>G p.T603A | Missense Mutation (SNP) | VAF 39/83 reads (47%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.956); catalogued as COSV100611036; called by muse, mutect2, varscan2
- ZNF432 | c.763C>G p.H255D | Missense Mutation (SNP) | VAF 55/75 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV99659256; called by muse, mutect2, varscan2
- ZNF479 | c.433G>A p.V145I | Missense Mutation (SNP) | VAF 48/137 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.112); catalogued as COSV100482766; called by muse, mutect2
- ARMCX1 | c.891_892dup p.C298Sfs*13 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- ATRX | c.3004_3007del p.V1002Lfs*30 | Frame Shift Del (DEL) | VAF 60/81 reads (74%) | called by mutect2, pindel, varscan2
- EFCAB14 | c.580-5_580-2del p.X194_splice | Splice Site (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel
- GEN1 | c.1062_1064del p.L355del | In Frame Del (DEL) | VAF 13/51 reads (25%) | called by mutect2, pindel, varscan2
- C7orf31 | c.468C>T p.R156= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as rs375479092; called by muse, mutect2, varscan2
- KDM5B | c.1149G>T p.G383= | Silent (SNP) | VAF 12/37 reads (32%) | catalogued as COSV99350702; called by muse, mutect2, varscan2
- NLRP5 | c.375G>A p.T125= | Silent (SNP) | VAF 16/20 reads (80%) | catalogued as rs370612026; ClinVar: likely benign; called by muse, mutect2, varscan2
- TRIM22 | c.711C>G p.L237= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs376156323; called by muse, mutect2
- GUF1 | c.*1T>C | 3'UTR (SNP) | VAF 18/39 reads (46%) | catalogued as COSV99776931; called by muse, mutect2, varscan2
